Somatic mutation profile of cancer-model specimen HCM-BROD-0829-C71-85A (Adherent Cell Line, passage 10; aliquot HCM-BROD-0829-C71-85A-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0829-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,277 days).
Specimen HCM-BROD-0829-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01d051aa-f081-4e6d-a1ca-e3cb0c8a82f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0829-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0829-C71-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cc78bbf-4f5f-40e5-8edf-da9bfea48f9d

The open-access MAF lists 79 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 20, Nonsense Mutation 7, Intron 2, 5'UTR 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 126/272 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, varscan2
- PDGFRA | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 3518/3957 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57265219, COSV57268286, COSV57271923; called by muse, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 134/319 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.2833C>T p.R945W | Missense Mutation (SNP) | VAF 235/460 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs565789183; called by muse, mutect2, varscan2
- ATF7 | c.488G>A p.R163H (on ENST00000548446 / NM_001366555.2; = p.R152H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 192/407 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as rs768505148, COSV60644493; called by muse, mutect2, varscan2
- CASR | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as rs1287075426, COSV56139780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL1A2 | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 122/433 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs772473302; called by muse, mutect2, varscan2
- DDIAS | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111486049; called by mutect2, varscan2
- DNAH2 | c.8641C>T p.R2881C | Missense Mutation (SNP) | VAF 242/459 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773830086; called by muse, mutect2, varscan2
- DSG3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV57129970; called by muse, mutect2
- EYS | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs957725168; called by muse, mutect2, varscan2
- FAM216B | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 112/233 reads (48%) | catalogued as rs1853636; called by muse, mutect2, varscan2
- FNDC11 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 34/532 reads (6%) | catalogued as rs1472785735; called by muse, mutect2
- GPR6 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 242/511 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51571736; called by muse, mutect2, varscan2
- HHIPL2 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 194/375 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as rs377410734, COSV100596740; called by muse, mutect2, varscan2
- HYDIN | c.11006C>T p.A3669V | Missense Mutation (SNP) | VAF 94/287 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749577224, COSV66885493; called by muse, mutect2, varscan2
- KEL | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 251/778 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142497392, COSV100787190; called by muse, mutect2, varscan2
- KLK10 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs142960865; called by muse, mutect2, varscan2
- MSH4 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 139/252 reads (55%) | catalogued as rs748663214, COSV54203285; called by muse, mutect2, varscan2
- MUC16 | c.43425G>A p.L14475= | Splice Region (SNP) | VAF 72/142 reads (51%) | catalogued as COSV101109902; called by mutect2, varscan2
- MUC3A | c.8842C>G p.Q2948E | Missense Mutation (SNP) | VAF 154/582 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.058); catalogued as rs1223005645, COSV100115362, COSV60212839; called by muse, mutect2, varscan2
- PKD1 | c.10898G>T p.S3633I (on ENST00000262304 / NM_001009944.3; = p.S3632I on NM_000296.4) | Missense Mutation (SNP) | VAF 211/445 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.4); catalogued as CD1210716, CD1210717; called by muse, mutect2, varscan2
- PPP2R3B | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 328/654 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1223797739; called by muse, mutect2, varscan2
- PYGO2 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 220/435 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63757121; called by muse, mutect2, varscan2
- RPL35 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 153/341 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs750326021; called by muse, mutect2, varscan2
- SH3BP5 | c.181A>G p.R61G | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53745033; called by muse, varscan2
- SZT2 | c.9659C>T p.P3220L (on ENST00000634258 / NM_001365999.1; = p.P3163L on NM_015284.4) | Missense Mutation (SNP) | VAF 188/426 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV65095501; called by muse, mutect2, varscan2
- TDRD6 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs779487173; called by muse, mutect2, varscan2
- TLX2 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 53/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768998577; called by muse, mutect2, varscan2
- WNT3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 52/618 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253456656, COSV56645344; called by muse, mutect2
- ZFAND1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 124/230 reads (54%) | catalogued as rs1173671877, COSV55106673; called by muse, mutect2, varscan2
- ZNF253 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 104/257 reads (40%) | catalogued as rs199597253; called by muse, mutect2, varscan2
- ADAMTSL5 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 27/619 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- ARAF | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C9 | c.514T>A p.F172I | Missense Mutation (SNP) | VAF 111/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSF3R | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 191/411 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- DEPDC1 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 147/272 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTHD1 | c.2172C>A p.H724Q (on ENST00000456874; = p.H559Q on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/308 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ERMN | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 170/318 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- EXT2 | c.1609A>C p.I537L (on ENST00000343631; = p.I570L on NM_000401.3) | Missense Mutation (SNP) | VAF 154/307 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- FAM205A | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FAM47B | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ISM1 | c.538T>C p.Y180H | Missense Mutation (SNP) | VAF 235/514 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- KITLG | c.782G>C p.S261T | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2A14 | c.632G>A p.C211Y | Missense Mutation (SNP) | VAF 154/462 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PITPNM2 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 141/306 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PLCH1 | c.454G>T p.E152* (on ENST00000340059 / NM_001130960.2; = p.E164* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 123/256 reads (48%) | called by muse, mutect2, varscan2
- POLD2 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R3C | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TG | c.2843G>T p.S948I | Missense Mutation (SNP) | VAF 163/327 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THSD7B | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- TMEM132C | c.3295A>C p.N1099H | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ZNF669 | c.1336del p.C446Vfs*25 | Frame Shift Del (DEL) | VAF 186/463 reads (40%) | called by mutect2, pindel, varscan2
- ZNF683 | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 16/448 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF830 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABLIM3 | c.1434C>T p.D478= | Silent (SNP) | VAF 14/448 reads (3%) | called by muse, mutect2
- ANK2 | c.354G>A p.K118= | Silent (SNP) | VAF 137/286 reads (48%) | catalogued as COSV100000052; called by muse, mutect2, varscan2
- BTNL2 | c.1008C>T p.D336= | Silent (SNP) | VAF 149/301 reads (50%) | catalogued as rs548150573, COSV66631013; called by muse, mutect2, varscan2
- CLDN9 | c.111C>G p.G37= | Silent (SNP) | VAF 246/453 reads (54%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.69G>A p.S23= | Silent (SNP) | VAF 162/164 reads (99%) | catalogued as COSV100758478; called by mutect2, varscan2
- DPPA3 | c.75C>T p.D25= | Silent (SNP) | VAF 90/225 reads (40%) | called by muse, mutect2, varscan2
- KLHL14 | c.219C>A p.G73= | Silent (SNP) | VAF 287/618 reads (46%) | catalogued as rs1417968367; called by muse, mutect2, varscan2
- L3MBTL3 | c.81G>A p.T27= | Silent (SNP) | VAF 146/307 reads (48%) | catalogued as rs762528427; called by muse, mutect2, varscan2
- MAN1C1 | c.63G>A p.Q21= | Silent (SNP) | VAF 279/572 reads (49%) | called by muse, mutect2, varscan2
- NLRP2 | c.864C>T p.D288= | Silent (SNP) | VAF 161/363 reads (44%) | catalogued as rs777161045, COSV54751910; called by muse, mutect2, varscan2
- PON3 | c.943A>C p.R315= | Silent (SNP) | VAF 132/519 reads (25%) | called by muse, mutect2, varscan2
- PTPRB | c.5154A>T p.S1718= | Silent (SNP) | VAF 156/308 reads (51%) | called by muse, mutect2, varscan2
- SCN1A | c.1764C>T p.N588= | Silent (SNP) | VAF 143/373 reads (38%) | catalogued as rs1026954517, COSV100322735; called by muse, mutect2, varscan2
- SERPINB7 | c.354C>T p.A118= | Silent (SNP) | VAF 79/163 reads (48%) | catalogued as rs766159379, COSV60532546; called by muse, mutect2, varscan2
- SNRPN | c.90C>A p.T30= | Silent (SNP) | VAF 170/308 reads (55%) | catalogued as rs1472464689, COSV57596293; called by muse, mutect2, varscan2
- TINAGL1 | c.489C>T p.S163= | Silent (SNP) | VAF 165/365 reads (45%) | catalogued as rs773638525; called by muse, mutect2, varscan2
- TRPM5 | c.1233G>A p.T411= | Silent (SNP) | VAF 28/564 reads (5%) | catalogued as rs199917878; called by muse, mutect2
- WDR17 | c.1953C>T p.H651= | Silent (SNP) | VAF 97/196 reads (49%) | catalogued as rs142429080; called by muse, mutect2, varscan2
- ZMYM1 | c.714C>T p.Y238= | Silent (SNP) | VAF 16/509 reads (3%) | catalogued as rs1406467540; called by muse, mutect2
- ZNF469 | c.4524C>T p.P1508= (on ENST00000437464; = p.P1536= on NM_001367624.2) | Silent (SNP) | VAF 164/352 reads (47%) | catalogued as rs746198528; called by muse, varscan2
- AGTPBP1 | c.-49G>C | 5'UTR (SNP) | VAF 172/331 reads (52%) | called by muse, mutect2, varscan2
- CASR | c.1378-6169G>A | Intron (SNP) | VAF 158/297 reads (53%) | catalogued as rs201536450, CM165782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRD | c.1059+103G>A | Intron (SNP) | VAF 329/679 reads (48%) | catalogued as rs778864072, COSV66079995; called by muse, mutect2, varscan2
- OPRM1 | c.-471G>C | 5'UTR (SNP) | VAF 122/274 reads (45%) | called by muse, mutect2, varscan2
